TCGA case TCGA-04-1342 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8727855e-120a-4216-a803-8cc6cd1159be

Demographics
Sex at birth: female; Race: white; Age at index: 80 years; Vital status: Dead; Days to death: 563 days (1.5 years).

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 80.8 years (29,501 days); Year of diagnosis: 2006; Method of diagnosis: Surgical Resection; FIGO stage: Stage IV; Tumor grade: G2; Prior treatment: No.
   Pathology details: Residual tumor measurement: >20 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 32 days; Days to treatment end: 142 days; Number of cycles: 6; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel + Doxorubicin + Paclitaxel + Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 170 days; Days to treatment end: 478 days (1.3 years); Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 563 days (1.5 years); Disease response: With Tumor.
- ECOG performance status: 2; Timepoint: Preoperative.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-04-1342-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2; Intermediate dimension: 1; Shortest dimension: 0.2.
  Slide TCGA-04-1342-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 91; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 9.
  Slide TCGA-04-1342-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 4; Percent stromal cells: 11.
- Sample TCGA-04-1342-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 1; Shortest dimension: 0.1.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: Taxol; Therapy regimen: Progression.
- Drug treatment 4: Pharmaceutical therapy drug name: Taxotere; Therapy regimen: Progression.

The TCGA Pan-Cancer Clinical Data Resource (Liu et al., Cell 2018) lists this case as redacted by TCGA at the time of its curation; its follow-up endpoints are therefore not restated here.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-04-1342-01A-01D-0428-01): tumor purity 0.79, ploidy 2.35, whole-genome doublings 0.
